Somatic mutation profile of tumor specimen C3N-05107-03 (aliquot CPT0438530006) from CPTAC case C3N-05107, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 59.1 years (21,598 days).
Specimen C3N-05107-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21344c5e-937b-4bfb-8023-2dfd988d84e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-05107-31 (Blood Derived Normal), aliquot CPT0444770002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3c5b502-78cd-4638-8fa2-aa1f6796a5e2

The open-access MAF lists 605 somatic variants for this specimen: 383 protein-altering or splice-affecting, 194 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 353, Silent 194, Nonsense Mutation 21, Intron 15, 3'UTR 5, Splice Region 3, 3'Flank 3, 5'Flank 2, RNA 2, Splice Site 2, Frame Shift Del 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 85/422 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- RAC1 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 92/310 reads (30%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as rs1057519874, COSV61821563, COSV61823187; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- SLC26A4 | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 83/396 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs370588279, CM030956, COSV55914262; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.395A>G p.K132R | Missense Mutation (SNP) | VAF 72/298 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1057519996, COSV52666637, COSV52701687, COSV52759171; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- A2M | c.1336C>T p.H446Y | Missense Mutation (SNP) | VAF 64/391 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.082); catalogued as COSV59389380, COSV59389750; called by muse, mutect2, varscan2
- ABCG8 | c.1144G>C p.D382H | Missense Mutation (SNP) | VAF 38/441 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.64); catalogued as COSV55390267; called by muse, mutect2
- ACAD10 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 53/354 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100564695; called by muse, mutect2, varscan2
- ACMSD | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 72/318 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267598885, COSV51606002, COSV51609903; called by muse, mutect2, varscan2
- ACSM2B | c.698A>T p.H233L | Missense Mutation (SNP) | VAF 62/381 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1310881419, COSV100313047; called by muse, mutect2, varscan2
- ADAM7 | c.1843-1G>A p.X615_splice | Splice Site (SNP) | VAF 33/238 reads (14%) | catalogued as rs754100215; called by muse, mutect2, varscan2
- ADAMTS16 | c.2599C>T p.P867S | Missense Mutation (SNP) | VAF 71/504 reads (14%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV99941200; called by muse, mutect2, varscan2
- ADAMTS2 | c.3155C>T p.S1052L | Missense Mutation (SNP) | VAF 64/354 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs535196543; called by muse, mutect2, varscan2
- ADAMTS2 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 99/563 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752401488; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRA2 | c.1373C>T p.S458L | Missense Mutation (SNP) | VAF 76/405 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as COSV59448129; called by muse, mutect2, varscan2
- ADGRV1 | c.18575G>A p.G6192E | Missense Mutation (SNP) | VAF 41/321 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs369354773; called by muse, mutect2, varscan2
- AGO4 | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as COSV64616595; called by muse, mutect2, varscan2
- ALK | c.3551G>A p.G1184E | Missense Mutation (SNP) | VAF 43/281 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66563806, COSV66590794; called by muse, mutect2, varscan2
- ALMS1 | c.5629G>A p.G1877R | Missense Mutation (SNP) | VAF 89/458 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.361); catalogued as rs1008875686; called by muse, mutect2, varscan2
- ANKRD18A | c.977G>A p.G326E | Missense Mutation (SNP) | VAF 49/226 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1330327660, COSV68802401; called by muse, mutect2, varscan2
- ANP32A | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 28/397 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.048); catalogued as COSV99143081; called by muse, mutect2
- APBB2 | c.638G>A p.R213K | Missense Mutation (SNP) | VAF 39/384 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766502178; called by muse, mutect2, varscan2
- APLNR | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 83/421 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs780061917, COSV57241774, COSV57243829; called by muse, mutect2, varscan2
- AQP8 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 66/347 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.331); catalogued as rs780410063, COSV54845299; called by muse, mutect2, varscan2
- ASPHD1 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 83/482 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.063); catalogued as rs1192513403; called by muse, mutect2, varscan2
- ATCAY | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 44/294 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as rs763099910, COSV56654027; called by muse, mutect2, varscan2
- ATP5F1B | c.1586C>T p.S529L | Missense Mutation (SNP) | VAF 51/337 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs144267158; called by muse, mutect2, varscan2
- BAHCC1 | c.6247G>A p.E2083K | Missense Mutation (SNP) | VAF 123/486 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.092); catalogued as rs201149766; called by muse, mutect2, varscan2
- BMP10 | c.985T>C p.Y329H | Missense Mutation (SNP) | VAF 73/447 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as rs929664859; called by muse, mutect2, varscan2
- BMS1 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 58/502 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV65732831; called by muse, mutect2
- BMX | c.2008C>T p.R670W | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as rs1029888196, COSV53023604; called by muse, mutect2, varscan2
- BRINP1 | c.1804C>T p.L602F | Missense Mutation (SNP) | VAF 62/331 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs1409902126; called by muse, mutect2, varscan2
- C19orf57 | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 111/596 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.069); catalogued as rs779707758; called by muse, mutect2, varscan2
- C5orf15 | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 30/352 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs1291023339; called by muse, mutect2
- CARD14 | c.1975G>A p.D659N | Missense Mutation (SNP) | VAF 73/245 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.111); catalogued as rs748534099, COSV60125575; called by muse, mutect2, varscan2
- CCDC144A | c.82A>G p.S28G | Missense Mutation (SNP) | VAF 90/410 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.153); catalogued as rs1294317489; called by muse, mutect2, varscan2
- CCDC39 | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 39/234 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56491461; called by muse, mutect2, varscan2
- CCDC65 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 62/494 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.609); catalogued as rs535147502, COSV56739881; called by muse, mutect2, varscan2
- CDC5L | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 59/338 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.453); catalogued as rs770063828; called by muse, mutect2, varscan2
- CDH10 | c.931G>A p.G311S | Missense Mutation (SNP) | VAF 47/532 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.922); catalogued as COSV100050890; called by muse, mutect2
- CDH12 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 63/438 reads (14%) | SIFT tolerated (0.85); PolyPhen benign (0.163); catalogued as COSV66396285, COSV66415403; called by muse, mutect2, varscan2
- CDH13 | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 63/447 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51864253; called by muse, mutect2, varscan2
- CFAP46 | c.7967C>T p.S2656F | Missense Mutation (SNP) | VAF 161/642 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.202); catalogued as rs374964573; called by muse, mutect2, varscan2
- CFH | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 68/394 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.166); catalogued as COSV62776162; called by muse, mutect2, varscan2
- CGNL1 | c.3163C>T p.L1055F | Missense Mutation (SNP) | VAF 53/313 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.184); catalogued as COSV99847529; called by muse, mutect2, varscan2
- CHRNG | c.231G>A p.W77* | Nonsense Mutation (SNP) | VAF 63/319 reads (20%) | catalogued as COSV51331530; called by muse, mutect2, varscan2
- CLDN2 | c.468G>A p.M156I | Missense Mutation (SNP) | VAF 95/253 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.622); catalogued as COSV61020890, COSV61021417; called by muse, mutect2, varscan2
- CNGB3 | c.1035G>A p.M345I | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as COSV60693964; called by muse, mutect2, varscan2
- CNN3 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 54/329 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV64637039; called by muse, mutect2, varscan2
- CNPPD1 | c.118T>C p.Y40H | Missense Mutation (SNP) | VAF 43/410 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99811367; called by muse, mutect2, varscan2
- CNR1 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 49/311 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.977); catalogued as COSV62990727; called by muse, mutect2, varscan2
- COL11A1 | c.3631G>A p.E1211K | Missense Mutation (SNP) | VAF 44/314 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1485916096, COSV62178338; called by muse, mutect2, varscan2
- COL6A2 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 134/563 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.094); catalogued as rs374504636; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL7A1 | c.2170G>A p.G724S | Missense Mutation (SNP) | VAF 59/282 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.071); catalogued as rs371102080, COSV60395959; called by muse, mutect2, varscan2
- COMMD4 | c.578C>T p.T193I | Missense Mutation (SNP) | VAF 86/403 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.072); catalogued as rs377076813; called by muse, mutect2, varscan2
- COQ8B | c.1387G>C p.A463P | Missense Mutation (SNP) | VAF 78/436 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV99425204; called by mutect2, varscan2
- CRACDL | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 95/565 reads (17%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.502); catalogued as rs367857987; called by muse, mutect2, varscan2
- CROCC | c.2248C>T p.Q750* | Nonsense Mutation (SNP) | VAF 50/299 reads (17%) | catalogued as COSV65012267; called by muse, mutect2, varscan2
- CSMD1 | c.3364C>T p.P1122S (on ENST00000520002; = p.P1121S on NM_033225.6) | Missense Mutation (SNP) | VAF 30/394 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59351885; called by muse, mutect2
- CYLC1 | c.227G>A p.W76* | Nonsense Mutation (SNP) | VAF 64/224 reads (29%) | catalogued as COSV61411277; called by muse, mutect2, varscan2
- CYP19A1 | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 60/330 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs577716822, COSV53061299; called by muse, varscan2
- CYRIA | c.353C>T p.T118I | Missense Mutation (SNP) | VAF 38/472 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as rs762840433; called by muse, mutect2
- DENND4B | c.1597G>A p.D533N | Missense Mutation (SNP) | VAF 71/318 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.351); catalogued as rs1312685691, COSV63411890; called by muse, mutect2, varscan2
- DNAH3 | c.5002G>A p.E1668K | Missense Mutation (SNP) | VAF 59/381 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.103); catalogued as rs762197687, COSV54548298; called by muse, mutect2, varscan2
- DNAH5 | c.6867G>A p.M2289I | Missense Mutation (SNP) | VAF 57/319 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as rs1349926561; called by muse, mutect2, varscan2
- DOCK9 | c.4814C>T p.S1605F (on ENST00000376460 / NM_001366676.2; = p.S1606F on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/456 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV59619461, COSV59619721; called by muse, mutect2, varscan2
- DPRX | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 51/305 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs761892759, COSV64949245; called by muse, mutect2, varscan2
- DPYSL5 | c.1669G>A p.G557R | Missense Mutation (SNP) | VAF 64/331 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs755205638, COSV56512346, COSV99982937; called by muse, mutect2, varscan2
- DPYSL5 | c.1670G>A p.G557E | Missense Mutation (SNP) | VAF 64/330 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56515784; called by muse, mutect2, varscan2
- EGFR | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 93/378 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51865345; called by muse, mutect2, varscan2
- EGR2 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 53/485 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs745823802; called by muse, mutect2, varscan2
- ELMOD2 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 11/254 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV60270275; called by muse, mutect2
- FAM110C | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 127/588 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1482994507; called by muse, mutect2, varscan2
- FER1L6 | c.3526C>T p.Q1176* | Nonsense Mutation (SNP) | VAF 22/323 reads (7%) | catalogued as COSV67553216; called by muse, mutect2
- FGFR4 | c.2258A>T p.E753V | Missense Mutation (SNP) | VAF 51/294 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1562078782; called by muse, mutect2, varscan2
- FMNL3 | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 44/358 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99035955; called by muse, mutect2, varscan2
- FRMPD2 | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 59/399 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.491); catalogued as rs1393232291; called by muse, mutect2, varscan2
- FZD9 | c.1652G>A p.R551Q | Missense Mutation (SNP) | VAF 131/435 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs782597771; called by muse, varscan2
- GALNS | c.1441C>T p.P481S | Missense Mutation (SNP) | VAF 95/514 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.743); catalogued as rs781512359; called by muse, mutect2
- GIMAP6 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 155/591 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV61033100, COSV61034789; called by muse, mutect2, varscan2
- GOLGB1 | c.3601C>T p.L1201F | Missense Mutation (SNP) | VAF 68/470 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.732); catalogued as COSV61470286; called by muse, mutect2, varscan2
- GPR84 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 57/518 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs764900108, COSV57210182; called by muse, mutect2, varscan2
- GTSF1 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 36/308 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV59938994; called by muse, mutect2, varscan2
- HECW1 | c.2314G>A p.E772K | Missense Mutation (SNP) | VAF 179/607 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.058); catalogued as COSV101223218; called by muse, mutect2, varscan2
- HOXB4 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 71/264 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs1034769921; called by muse, mutect2, varscan2
- HPN | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 102/580 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as rs1418048764; called by muse, mutect2, varscan2
- HTR3A | c.1164G>A p.M388I | Missense Mutation (SNP) | VAF 56/370 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1348683604, COSV100248592; called by muse, mutect2, varscan2
- ITGA6 | c.2275C>T p.P759S (on ENST00000442250; = p.P720S on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/354 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.974); catalogued as COSV99905540; called by muse, mutect2
- ITGA7 | c.3466C>T p.P1156S (on ENST00000555728; = p.P1112S on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/672 reads (10%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as rs1413641636, COSV57698731; called by muse, mutect2
- JAKMIP2 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 55/430 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV54609259; called by muse, mutect2, varscan2
- KCNH7 | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 38/451 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV59794391, COSV59795868, COSV59810588; called by muse, mutect2
- KIR2DL1 | c.704G>T p.S235I | Missense Mutation (SNP) | VAF 62/375 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV52414941; called by muse, mutect2, varscan2
- KLK10 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 71/391 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as rs768201692; called by muse, mutect2, varscan2
- LIPF | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 55/415 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1201888545; called by muse, mutect2, varscan2
- LTBP2 | c.1924G>A p.G642S | Missense Mutation (SNP) | VAF 36/356 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760385920; called by muse, mutect2
- MAP2K3 | c.519C>T p.I173= (on ENST00000342679 / NM_145109.3; = p.I144= on NM_002756.4) | Splice Region (SNP) | VAF 52/512 reads (10%) | catalogued as rs926420103, COSV100383707, COSV57567452; called by muse, mutect2
- MAP9 | c.229C>T p.H77Y | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.544); catalogued as rs187054827; called by muse, mutect2
- MAPKAPK3 | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 72/305 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63598523; called by muse, mutect2, varscan2
- MDC1 | c.5500C>A p.Q1834K | Missense Mutation (SNP) | VAF 66/814 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV64523536; called by muse, mutect2
- MECOM | c.922C>T p.P308S (on ENST00000468789 / NM_001105078.4; = p.P496S on NM_004991.4) | Missense Mutation (SNP) | VAF 101/552 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.158); catalogued as COSV52959050; called by muse, mutect2, varscan2
- MIA3 | c.495G>C p.M165I | Missense Mutation (SNP) | VAF 59/388 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV60515853; called by muse, mutect2, varscan2
- MOGAT2 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 28/360 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52219116; called by muse, mutect2
- MUC16 | c.32909G>A p.G10970E | Missense Mutation (SNP) | VAF 66/432 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.02); catalogued as COSV67470916; called by muse, mutect2, varscan2
- MUC16 | c.32908G>A p.G10970R | Missense Mutation (SNP) | VAF 68/436 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.136); catalogued as rs1390595563; called by muse, mutect2, varscan2
- MUC16 | c.25258G>A p.E8420K | Missense Mutation (SNP) | VAF 100/526 reads (19%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.556); catalogued as rs1478032224, COSV67502447; called by muse, mutect2, varscan2
- MUC16 | c.11617G>A p.E3873K | Missense Mutation (SNP) | VAF 66/442 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); catalogued as COSV67445151, COSV67464700; called by muse, mutect2, varscan2
- MUC21 | c.16G>A p.G6R | Missense Mutation (SNP) | VAF 76/443 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.191); catalogued as rs779650927, COSV66220675; called by muse, mutect2, varscan2
- MYH7B | c.1651G>A p.D551N | Missense Mutation (SNP) | VAF 17/333 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.181); catalogued as COSV53420069; called by muse, mutect2
- NCKAP5 | c.4417G>A p.E1473K | Missense Mutation (SNP) | VAF 93/445 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs911991502, COSV58464584; called by muse, mutect2, varscan2
- NELFE | c.305G>A p.G102E | Missense Mutation (SNP) | VAF 70/542 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1217873794; called by muse, mutect2, varscan2
- NELFE | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 69/539 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779927864; called by muse, mutect2, varscan2
- NET1 | c.1405C>T p.R469C (on ENST00000355029 / NM_001047160.3; = p.R415C on NM_005863.5) | Missense Mutation (SNP) | VAF 58/271 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs150542987; called by muse, mutect2, varscan2
- NFASC | c.799G>A p.E267K (on ENST00000339876 / NM_001378329.1; = p.E278K on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/290 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV100366053; called by muse, mutect2, varscan2
- NLRP14 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 42/510 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.299); catalogued as COSV55066086, COSV55070084; called by muse, mutect2
- NPHP4 | c.3469C>T p.P1157S | Missense Mutation (SNP) | VAF 58/293 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as COSV65398745; called by muse, mutect2, varscan2
- NRXN1 | c.641G>A p.G214E | Missense Mutation (SNP) | VAF 99/540 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV68015235; called by muse, mutect2, varscan2
- NTN1 | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 79/317 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1567725426, COSV51489555; called by muse, mutect2, varscan2
- OASL | c.327G>A p.W109* | Nonsense Mutation (SNP) | VAF 57/411 reads (14%) | catalogued as COSV57478975; called by muse, mutect2, varscan2
- OGDHL | c.2948G>A p.G983E | Missense Mutation (SNP) | VAF 75/370 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65100647; called by muse, mutect2, varscan2
- OR10G9 | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 71/417 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV66685778; called by muse, mutect2, varscan2
- OR13A1 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 85/613 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1334879701, COSV65572354, COSV65573278; called by muse, mutect2, varscan2
- OR4K13 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 28/414 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV100237599; called by muse, mutect2
- OR51G2 | c.570G>A p.M190I | Missense Mutation (SNP) | VAF 48/538 reads (9%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.989); catalogued as rs1444169047, COSV58991851; called by muse, mutect2
- OR6C6 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 49/401 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV64455907; called by muse, mutect2, varscan2
- OR8J3 | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 58/313 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs550603090, COSV56879225; called by muse, mutect2, varscan2
- PARD3B | c.3380C>T p.P1127L (on ENST00000406610 / NM_001302769.2; = p.P1058L on NM_057177.7) | Missense Mutation (SNP) | VAF 83/467 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV62525992; called by muse, mutect2, varscan2
- PCDH18 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 47/393 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.856); catalogued as rs866046766; called by muse, mutect2, varscan2
- PCED1B | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 69/453 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71394939, COSV71395643; called by muse, mutect2, varscan2
- PDE1C | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 83/342 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV100373692, COSV58506161; called by muse, mutect2, varscan2
- POM121L2 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 85/504 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV66275147; called by muse, mutect2, varscan2
- PPP1R9A | c.1450C>T p.P484S | Missense Mutation (SNP) | VAF 88/386 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99194870; called by muse, mutect2, varscan2
- PRKG2 | c.283C>T p.Q95* | Nonsense Mutation (SNP) | VAF 42/376 reads (11%) | catalogued as rs1176638156, COSV52331310; called by muse, mutect2, varscan2
- PROSER3 | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 103/540 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs751461933; called by muse, varscan2
- PSD | c.1036G>A p.G346S | Missense Mutation (SNP) | VAF 112/535 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs780416746; called by muse, mutect2, varscan2
- PYGL | c.1476G>A p.W492* | Nonsense Mutation (SNP) | VAF 50/320 reads (16%) | catalogued as COSV53588430; called by muse, mutect2, varscan2
- RANBP10 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 61/342 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV58160964; called by muse, mutect2, varscan2
- RERG | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 51/393 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.058); catalogued as COSV56999937, COSV99917413; called by muse, mutect2, varscan2
- RFPL1 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 113/702 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100585909; called by muse, varscan2
- RIPOR3 | c.2443C>T p.Q815* | Nonsense Mutation (SNP) | VAF 93/619 reads (15%) | catalogued as rs751702128, COSV99246988; called by muse, mutect2, varscan2
- RRAS2 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 29/272 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs782490571, COSV99819013; called by muse, mutect2, varscan2
- RSPH1 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 62/285 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs376824155; called by muse, mutect2, varscan2
- RYR2 | c.1154G>A p.G385E | Missense Mutation (SNP) | VAF 42/227 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs373148638; called by muse, mutect2, varscan2
- S1PR1 | c.213G>A p.W71* | Nonsense Mutation (SNP) | VAF 90/494 reads (18%) | catalogued as COSV100541708, COSV59512997; called by muse, mutect2, varscan2
- SCN5A | c.2145G>A p.M715I | Missense Mutation (SNP) | VAF 110/490 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs1334057069, COSV61136950; called by muse, mutect2, varscan2
- SLC24A3 | c.1270G>T p.E424* | Nonsense Mutation (SNP) | VAF 100/463 reads (22%) | catalogued as COSV60125794; called by muse, mutect2, varscan2
- SLC25A18 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 125/512 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV59408232; called by muse, mutect2, varscan2
- SLC9B1 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV56467336; called by muse, mutect2
- SLITRK5 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 63/407 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.383); catalogued as COSV61521535; called by muse, mutect2, varscan2
- SNORC | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 80/485 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.127); catalogued as rs755367305, COSV58795106; called by muse, mutect2, varscan2
- SNPH | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 80/510 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs562927965; called by muse, mutect2, varscan2
- SORL1 | c.1603C>T p.P535S | Missense Mutation (SNP) | VAF 76/307 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV52762503; called by muse, mutect2, varscan2
- SOS2 | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 35/372 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs1364027643, COSV53567356; called by muse, mutect2
- STOX2 | c.2003C>T p.S668L | Missense Mutation (SNP) | VAF 49/506 reads (10%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as rs755061535, COSV57852198; called by muse, mutect2
- SULF1 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 52/280 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760249922; called by muse, mutect2, varscan2
- TAS2R31 | c.226T>C p.Y76H | Missense Mutation (SNP) | VAF 53/500 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.049); catalogued as rs1437804712; called by muse, varscan2
- TCAF1 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 48/602 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV100584750; called by muse, mutect2
- TCF24 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 23/248 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1241447961; called by muse, mutect2
- TECTA | c.5978G>A p.R1993Q | Missense Mutation (SNP) | VAF 59/268 reads (22%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); catalogued as rs199881827; called by muse, mutect2, varscan2
- TEDC1 | c.1004C>T p.P335L (on ENST00000392523 / NM_001367178.1; = p.P266L on NM_001134875.1) | Missense Mutation (SNP) | VAF 70/402 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs782685957, COSV58154848; called by muse, mutect2, varscan2
- TFAP2B | c.1165C>T p.P389S | Missense Mutation (SNP) | VAF 102/508 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV53830953; called by muse, mutect2, varscan2
- THSD4 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 29/334 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV55966472; called by muse, mutect2
- TIMD4 | c.131C>T p.S44F | Missense Mutation (SNP) | VAF 64/453 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV50854909; called by muse, mutect2, varscan2
- TKTL1 | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 92/302 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV54213089; called by muse, mutect2, varscan2
- TMEM109 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 87/448 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.801); catalogued as COSV99134321; called by muse, mutect2, varscan2
- TMEM132D | c.233G>T p.R78L | Missense Mutation (SNP) | VAF 66/446 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs757474690, COSV101398995, COSV70623917; called by muse, mutect2, varscan2
- TMPRSS12 | c.604G>A p.G202R | Missense Mutation (SNP) | VAF 59/348 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs568316978, COSV68256878; called by muse, mutect2, varscan2
- TNFAIP8L1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 54/308 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV59419924; called by muse, mutect2
- TNNC1 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 64/374 reads (17%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); catalogued as rs397516849, COSV51768110; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TPTE | c.1069G>A p.E357K (on ENST00000618007 / NM_199261.4; = p.E339K on NM_199259.4) | Missense Mutation (SNP) | VAF 34/660 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.089); catalogued as rs575650462; called by muse, mutect2
- TRANK1 | c.8252C>T p.S2751F | Missense Mutation (SNP) | VAF 93/555 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.202); catalogued as rs749164015; called by muse, mutect2, varscan2
- TRANK1 | c.537G>A p.M179I | Missense Mutation (SNP) | VAF 99/400 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV57141440; called by muse, mutect2, varscan2
- TRIO | c.3224C>T p.T1075I | Missense Mutation (SNP) | VAF 37/236 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60082952; called by muse, mutect2, varscan2
- TRPM8 | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 76/464 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV100223757; called by muse, mutect2, varscan2
- TSKS | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 76/434 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.241); catalogued as rs138198069; called by muse, mutect2, varscan2
- TTN | c.71959G>A p.D23987N (on ENST00000591111; = p.D16563N on NM_003319.4) | Missense Mutation (SNP) | VAF 42/417 reads (10%) | PolyPhen probably damaging (0.996); catalogued as COSV60288597; called by muse, mutect2
- TTN | c.65260G>A p.E21754K (on ENST00000591111; = p.E14330K on NM_003319.4) | Missense Mutation (SNP) | VAF 73/438 reads (17%) | PolyPhen benign (0.254); catalogued as rs1397813682, COSV59894055; called by muse, mutect2, varscan2
- TTN | c.44257G>A p.D14753N (on ENST00000591111; = p.D7329N on NM_003319.4) | Missense Mutation (SNP) | VAF 92/449 reads (20%) | PolyPhen probably damaging (0.998); catalogued as rs765265590, COSV59935178; called by muse, mutect2, varscan2
- TUBGCP4 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as rs542122190, COSV53018505; called by muse, mutect2, varscan2
- UBQLN3 | c.931G>A p.G311R | Missense Mutation (SNP) | VAF 46/488 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV61164704; called by muse, mutect2
- UBR1 | c.3336T>G p.N1112K | Missense Mutation (SNP) | VAF 74/361 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0.015); catalogued as rs1159425116; called by muse, mutect2, varscan2
- UGT1A5 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 46/414 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.114); catalogued as COSV59394524; called by muse, mutect2, varscan2
- USP4 | c.2617C>T p.H873Y | Missense Mutation (SNP) | VAF 86/331 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55535396; called by muse, mutect2, varscan2
- USP51 | c.487del p.R163Gfs*8 | Frame Shift Del (DEL) | VAF 77/265 reads (29%) | catalogued as COSV72352064; called by mutect2, pindel, varscan2
- VPS37D | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 127/455 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs782009913; called by muse, mutect2, varscan2
- WDR59 | c.2801C>T p.S934L | Missense Mutation (SNP) | VAF 96/506 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.968); catalogued as rs776566274, COSV50933412; called by muse, mutect2, varscan2
- ZAN | c.2935C>T p.P979S | Missense Mutation (SNP) | VAF 184/674 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1355103405; called by mutect2, varscan2
- ZBBX | c.1558G>T p.D520Y | Missense Mutation (SNP) | VAF 60/358 reads (17%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.459); catalogued as COSV56782104; called by muse, mutect2, varscan2
- ZNF443 | c.1042C>T p.H348Y | Missense Mutation (SNP) | VAF 56/454 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.241); catalogued as rs747859377; called by muse, mutect2, varscan2
- ZNF594 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 85/403 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.071); catalogued as rs1450002211; called by muse, mutect2, varscan2
- ABCC6 | c.2830_2831del p.T944Pfs*93 | Frame Shift Del (DEL) | VAF 79/660 reads (12%) | called by mutect2, pindel, varscan2
- ABHD17B | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 60/304 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ACAD10 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 53/357 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACMSD | c.618G>A p.M206I | Missense Mutation (SNP) | VAF 52/287 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ADAM20 | c.1612G>A p.G538R | Missense Mutation (SNP) | VAF 52/478 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AHNAK | c.1207C>T p.Q403* | Nonsense Mutation (SNP) | VAF 37/367 reads (10%) | called by muse, mutect2, varscan2
- ALDH2 | c.1075G>A p.G359R | Missense Mutation (SNP) | VAF 33/295 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ANK1 | c.5011T>G p.S1671A | Missense Mutation (SNP) | VAF 60/373 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ANKFN1 | c.609C>T p.H203= | Splice Region (SNP) | VAF 59/240 reads (25%) | called by muse, mutect2, varscan2
- ANKRD2 | c.595A>C p.K199Q | Missense Mutation (SNP) | VAF 47/362 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- APMAP | c.152C>T p.T51I | Missense Mutation (SNP) | VAF 24/354 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2
- ARAP2 | c.4618G>A p.D1540N | Missense Mutation (SNP) | VAF 30/276 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARFGEF1 | c.3459T>G p.D1153E | Missense Mutation (SNP) | VAF 47/308 reads (15%) | SIFT tolerated (0.97); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- ARID5A | c.1765C>T p.H589Y | Missense Mutation (SNP) | VAF 40/403 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- BBX | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 57/295 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- BTBD17 | c.1022C>A p.T341K | Missense Mutation (SNP) | VAF 71/547 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- BTNL3 | c.1397G>A p.G466E | Missense Mutation (SNP) | VAF 67/447 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- C10orf90 | c.1528C>T p.P510S | Missense Mutation (SNP) | VAF 46/309 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C1orf210 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 108/539 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C1orf87 | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 64/379 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- C6orf132 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 62/376 reads (16%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- CCDC175 | c.1165C>T p.H389Y | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCNB3 | c.2863C>T p.P955S | Missense Mutation (SNP) | VAF 95/261 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDH26 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 69/374 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- CDK13 | c.3080G>A p.R1027K | Missense Mutation (SNP) | VAF 52/524 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.119); called by muse, mutect2
- CEP89 | c.1903G>A p.G635R | Missense Mutation (SNP) | VAF 55/328 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CES1 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 80/1088 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.34); called by muse, mutect2
- CFAP221 | c.2189C>T p.S730F | Missense Mutation (SNP) | VAF 59/324 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- CFAP54 | c.1928G>A p.W643* | Nonsense Mutation (SNP) | VAF 34/176 reads (19%) | called by muse, mutect2, varscan2
- CHD6 | c.6907T>A p.L2303M | Missense Mutation (SNP) | VAF 60/368 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- CMYA5 | c.3995C>T p.P1332L | Missense Mutation (SNP) | VAF 41/478 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.84); called by muse, mutect2
- COL28A1 | c.689T>A p.L230* | Nonsense Mutation (SNP) | VAF 20/358 reads (6%) | called by muse, mutect2
- COL4A5 | c.2893G>A p.E965K | Missense Mutation (SNP) | VAF 67/228 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- COL5A1 | c.2485G>A p.G829R | Missense Mutation (SNP) | VAF 63/305 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A6 | c.2074A>T p.M692L | Missense Mutation (SNP) | VAF 103/510 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- COPG2 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 38/491 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.797); called by muse, mutect2
- COX6B2 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 64/340 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPLX2 | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 50/562 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0.025); called by muse, mutect2
- CPNE2 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 42/336 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- CYP11A1 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 35/415 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.506); called by muse, mutect2
- CYP2C18 | c.640C>T p.Q214* | Nonsense Mutation (SNP) | VAF 14/175 reads (8%) | called by muse, mutect2
- DAB2 | c.248G>A p.G83D | Missense Mutation (SNP) | VAF 55/323 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- DAXX | c.2101C>T p.P701S | Missense Mutation (SNP) | VAF 159/825 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- DCDC1 | c.1165G>A p.G389R | Missense Mutation (SNP) | VAF 66/309 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DDC | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 81/300 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- DENND5B | c.2881G>A p.V961I | Missense Mutation (SNP) | VAF 48/412 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- DLGAP2 | c.1747G>A p.D583N | Missense Mutation (SNP) | VAF 61/658 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DNAH6 | c.8664G>A p.M2888I | Missense Mutation (SNP) | VAF 41/356 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- DNAH8 | c.2866G>A p.E956K | Missense Mutation (SNP) | VAF 39/224 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNHD1 | c.9200C>T p.P3067L | Missense Mutation (SNP) | VAF 38/362 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- DSG3 | c.2549G>A p.G850E | Missense Mutation (SNP) | VAF 48/324 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EIF3A | c.3349C>T p.R1117* | Nonsense Mutation (SNP) | VAF 86/673 reads (13%) | called by muse, mutect2, varscan2
- EPYC | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 40/412 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ERCC2 | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 33/227 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- FAM186A | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 39/331 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- FAM186B | c.1901C>T p.S634F | Missense Mutation (SNP) | VAF 80/531 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FAM227A | c.1334G>A p.G445D | Missense Mutation (SNP) | VAF 89/470 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FRAS1 | c.3076C>T p.L1026F | Missense Mutation (SNP) | VAF 32/426 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.015); called by muse, mutect2
- FRMD4B | c.47G>A p.G16D | Missense Mutation (SNP) | VAF 120/451 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GAD2 | c.862G>A p.G288R | Missense Mutation (SNP) | VAF 81/362 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GIMAP4 | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 96/502 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GLI1 | c.367C>T p.H123Y | Missense Mutation (SNP) | VAF 53/264 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GLYATL3 | c.121C>T p.Q41* | Nonsense Mutation (SNP) | VAF 59/339 reads (17%) | called by muse, mutect2, varscan2
- GOLGA8T | c.1274A>T p.E425V | Missense Mutation (SNP) | VAF 31/438 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.383); called by muse, mutect2
- GREM1 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 78/338 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HHIP | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 19/217 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2
- HIVEP2 | c.5873C>T p.P1958L | Missense Mutation (SNP) | VAF 71/340 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- HOXA10 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 65/642 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); called by muse, mutect2
- HTR2B | c.887C>T p.S296L | Missense Mutation (SNP) | VAF 58/562 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2
- IGLV4-3 | c.258G>A p.M86I | Missense Mutation (SNP) | VAF 82/436 reads (19%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- INPP5D | c.2233C>T p.Q745* (on ENST00000445964 / NM_001017915.3; = p.Q744* on NM_005541.5) | Nonsense Mutation (SNP) | VAF 63/363 reads (17%) | called by muse, mutect2, varscan2
- IP6K1 | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 93/432 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- IRAG2 | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 38/330 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- ITSN2 | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 39/343 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- KALRN | c.908A>G p.K303R | Missense Mutation (SNP) | VAF 60/360 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KCNH8 | c.244C>T p.Q82* | Nonsense Mutation (SNP) | VAF 65/342 reads (19%) | called by muse, mutect2, varscan2
- KCNK18 | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 72/365 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNQ3 | c.2410C>T p.P804S | Missense Mutation (SNP) | VAF 104/528 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KCP | c.3233C>T p.P1078L (on ENST00000620378; = p.P1138L on NM_001366122.1) | Missense Mutation (SNP) | VAF 37/442 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2
- KDM2B | c.2762C>T p.T921I | Missense Mutation (SNP) | VAF 120/590 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- KIF19 | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 60/253 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- KNTC1 | c.6391A>G p.N2131D | Missense Mutation (SNP) | VAF 25/236 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRP10 | c.346dup p.Y116Lfs*45 | Frame Shift Ins (INS) | VAF 91/516 reads (18%) | called by mutect2, pindel, varscan2
- LRRC70 | c.532G>A p.G178S | Missense Mutation (SNP) | VAF 28/313 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.942); called by muse, mutect2
- LRRC70 | c.533G>A p.G178D | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); called by muse, mutect2
- LRRK1 | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 87/444 reads (20%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRN2 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 81/453 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- MAGEL2 | c.1291C>T p.R431* | Nonsense Mutation (SNP) | VAF 83/727 reads (11%) | called by muse, mutect2, varscan2
- MAP3K21 | c.2695C>T p.P899S | Missense Mutation (SNP) | VAF 50/282 reads (18%) | SIFT tolerated (0.76); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MAP4K2 | c.1999G>A p.G667R | Missense Mutation (SNP) | VAF 102/505 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MAP4K5 | c.776C>T p.T259I | Missense Mutation (SNP) | VAF 28/319 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.073); called by muse, mutect2
- MAPRE3 | c.758G>A p.G253D | Missense Mutation (SNP) | VAF 51/300 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MDFIC | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 28/368 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MGAM2 | c.5693C>T p.P1898L | Missense Mutation (SNP) | VAF 132/484 reads (27%) | SIFT tolerated, low confidence (0.08); called by muse, mutect2, varscan2
- MINDY4 | c.2026A>G p.S676G | Missense Mutation (SNP) | VAF 71/678 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MINDY4B | c.500G>T p.G167V | Missense Mutation (SNP) | VAF 50/334 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- MINDY4B | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 50/339 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- MOGAT1 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 85/405 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MROH2A | c.4266G>A p.V1422= | Splice Region (SNP) | VAF 69/332 reads (21%) | called by muse, mutect2, varscan2
- MYH11 | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 69/440 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MYLIP | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 34/247 reads (14%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NBEAL2 | c.3248C>G p.A1083G | Missense Mutation (SNP) | VAF 99/493 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- NBPF3 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 67/391 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- NDUFC2 | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 47/312 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NLRP2 | c.3145C>T p.H1049Y | Missense Mutation (SNP) | VAF 74/441 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- NPW | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 73/355 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- NR2E1 | c.1021G>A p.G341R | Missense Mutation (SNP) | VAF 61/249 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- NRAP | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 31/305 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRAP | c.489A>T p.Q163H | Missense Mutation (SNP) | VAF 28/275 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.009); called by mutect2, varscan2
- NTSR2 | c.574C>T p.R192* | Nonsense Mutation (SNP) | VAF 46/489 reads (9%) | called by muse, mutect2
- OPN5 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 62/384 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- OR52E8 | c.406C>T p.L136F | Missense Mutation (SNP) | VAF 52/632 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); called by muse, mutect2
- OTUD1 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 112/665 reads (17%) | SIFT tolerated (0.77); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PABPC3 | c.550G>A p.G184R | Missense Mutation (SNP) | VAF 91/476 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.303); called by muse, varscan2
- PAPPA2 | c.455G>A p.R152K | Missense Mutation (SNP) | VAF 55/322 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PAPPA2 | c.3604A>G p.K1202E | Missense Mutation (SNP) | VAF 55/350 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PC | c.253C>T p.L85F | Missense Mutation (SNP) | VAF 43/476 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2
- PCDHGA5 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 43/425 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGB5 | c.1480C>T p.P494S | Missense Mutation (SNP) | VAF 78/486 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- PCK1 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 67/457 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCLO | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 55/495 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCNX2 | c.1412G>A p.G471E | Missense Mutation (SNP) | VAF 85/474 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHLDB2 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 95/441 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- PHYHIPL | c.538A>T p.M180L | Missense Mutation (SNP) | VAF 53/308 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLIN4 | c.1250G>A p.G417D (on ENST00000301286; = p.G432D on NM_001367868.2) | Missense Mutation (SNP) | VAF 116/563 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PNPLA8 | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 34/304 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- POMC | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 104/553 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPL | c.3629G>T p.R1210L | Missense Mutation (SNP) | VAF 90/530 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PPOX | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 50/238 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PRXL2A | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 79/386 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTAFR | c.985G>A p.V329I | Missense Mutation (SNP) | VAF 67/379 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- PWWP3B | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 117/333 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAB3GAP1 | c.2734G>A p.E912K | Missense Mutation (SNP) | VAF 34/284 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- RAPGEF4 | c.587C>T p.T196I | Missense Mutation (SNP) | VAF 35/285 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RGS20 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 73/500 reads (15%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ROBO3 | c.2797C>T p.P933S | Missense Mutation (SNP) | VAF 99/457 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- RP1 | c.993G>T p.M331I | Missense Mutation (SNP) | VAF 42/261 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- RP1 | c.2693G>A p.G898E | Missense Mutation (SNP) | VAF 47/469 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- RPL8 | c.640G>A p.G214S | Missense Mutation (SNP) | VAF 34/311 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RPS6KA6 | c.1432C>T p.P478S | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- RPUSD2 | c.524T>A p.L175Q | Missense Mutation (SNP) | VAF 75/387 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- RSPO1 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 88/454 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SALL1 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 83/477 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- SBK2 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 129/652 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCEL | c.975A>T p.K325N (on ENST00000349847 / NM_144777.3; = p.K305N on NM_003843.4) | Missense Mutation (SNP) | VAF 38/220 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- SCN2A | c.4330G>A p.E1444K | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.411); called by muse, mutect2
- SDHA | c.992C>A p.A331D | Missense Mutation (SNP) | VAF 34/441 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SDSL | c.316C>A p.L106M | Missense Mutation (SNP) | VAF 54/461 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- SELENON | c.678T>G p.S226R | Missense Mutation (SNP) | VAF 41/522 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.307); called by muse, mutect2
- SGSM1 | c.1526C>T p.S509F | Missense Mutation (SNP) | VAF 98/562 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- SI | c.1976C>T p.S659F | Missense Mutation (SNP) | VAF 53/309 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- SLC25A43 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 75/206 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SLITRK4 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 75/220 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- SMIM35 | c.86G>A p.S29N | Missense Mutation (SNP) | VAF 43/384 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- SMTN | c.2387C>T p.P796L | Missense Mutation (SNP) | VAF 114/449 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPNS2 | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 100/419 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- SULT1C3 | c.268C>T p.L90F | Missense Mutation (SNP) | VAF 51/246 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SUN3 | c.740G>A p.G247D | Missense Mutation (SNP) | VAF 40/486 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- SUN3 | c.739G>A p.G247S | Missense Mutation (SNP) | VAF 39/480 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- TACC3 | c.552A>T p.E184D | Missense Mutation (SNP) | VAF 49/408 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TBCB | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 91/509 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TDRD1 | c.1840C>T p.P614S | Missense Mutation (SNP) | VAF 34/225 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- TDRD15 | c.5452G>A p.G1818R | Missense Mutation (SNP) | VAF 47/232 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TENT5C | c.719G>A p.R240K | Missense Mutation (SNP) | VAF 66/470 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- TET2 | c.5810C>T p.P1937L | Missense Mutation (SNP) | VAF 36/432 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.601); called by muse, mutect2
- TIMD4 | c.1023G>T p.M341I | Missense Mutation (SNP) | VAF 29/268 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- TMEM168 | c.1181C>T p.S394F | Missense Mutation (SNP) | VAF 42/456 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- TMTC3 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 49/415 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TNFAIP8L1 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 46/273 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- TNFRSF25 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 127/590 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TPGS1 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 50/444 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.006); called by muse, mutect2
- TRAPPC10 | c.2506G>A p.E836K | Missense Mutation (SNP) | VAF 52/354 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- TRPC6 | c.1282C>T p.P428S | Missense Mutation (SNP) | VAF 33/324 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRPV6 | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 42/423 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- TTN | c.65617G>A p.E21873K (on ENST00000591111; = p.E14449K on NM_003319.4) | Missense Mutation (SNP) | VAF 45/419 reads (11%) | PolyPhen benign (0.259); called by muse, mutect2, varscan2
- UBR2 | c.1446-1G>A p.X482_splice | Splice Site (SNP) | VAF 55/310 reads (18%) | called by muse, mutect2, varscan2
- UGCG | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 64/320 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- UGT1A8 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 85/456 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- UIMC1 | c.664G>A p.G222S | Missense Mutation (SNP) | VAF 70/428 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- UNC13A | c.2946G>T p.K982N | Missense Mutation (SNP) | VAF 38/262 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- UTP20 | c.7237G>A p.E2413K | Missense Mutation (SNP) | VAF 40/233 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- VCPKMT | c.630T>G p.Y210* | Nonsense Mutation (SNP) | VAF 13/229 reads (6%) | called by muse, mutect2
- VN1R4 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 52/345 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- WIZ | c.5663C>T p.A1888V (on ENST00000673675 / NM_001371589.1; = p.A793V on NM_021241.3) | Missense Mutation (SNP) | VAF 61/389 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- WIZ | c.4053G>A p.M1351I (on ENST00000673675 / NM_001371589.1; = p.M256I on NM_021241.3) | Missense Mutation (SNP) | VAF 95/563 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- YY1AP1 | c.1529C>T p.P510L (on ENST00000295566 / NM_139118.2; = p.P453L on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 109/451 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ZNF318 | c.4808A>T p.N1603I | Missense Mutation (SNP) | VAF 65/396 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- ZNF471 | c.1678C>G p.Q560E | Missense Mutation (SNP) | VAF 80/459 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- ZNF594 | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 83/399 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- ZNF611 | c.1151C>T p.T384I | Missense Mutation (SNP) | VAF 61/414 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- ZNF69 | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 62/408 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ZNF716 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 34/410 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF839 | c.59G>A p.G20E (on ENST00000558850 / NM_001267827.1; = p.G136E on NM_018335.5) | Missense Mutation (SNP) | VAF 54/502 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.342); called by muse, mutect2
- ZNF99 | c.1318C>T p.L440F | Missense Mutation (SNP) | VAF 47/396 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- ZSCAN21 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 119/480 reads (25%) | SIFT tolerated (0.67); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- ABCB9 | c.474C>T p.F158= | Silent (SNP) | VAF 84/541 reads (16%) | catalogued as COSV54891704; called by muse, mutect2, varscan2
- ABLIM3 | c.408C>T p.S136= | Silent (SNP) | VAF 63/414 reads (15%) | called by muse, mutect2, varscan2
- ACBD5 | c.1212T>C p.S404= (on ENST00000375888 / NM_001352568.1; = p.S395= on NM_145698.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 71/338 reads (21%) | called by muse, mutect2, varscan2
- ACSL3 | c.1167G>A p.R389= | Silent (SNP) | VAF 44/195 reads (23%) | called by muse, mutect2, varscan2
- ACTR3C | c.613C>T p.L205= | Silent (SNP) | VAF 29/422 reads (7%) | called by muse, mutect2
- ADD2 | c.139C>T p.L47= | Silent (SNP) | VAF 41/404 reads (10%) | called by muse, mutect2, varscan2
- ADGRA1 | c.96C>T p.L32= | Silent (SNP) | VAF 40/349 reads (11%) | called by muse, mutect2, varscan2
- ADGRE3 | c.1734C>T p.V578= | Silent (SNP) | VAF 60/439 reads (14%) | called by muse, mutect2, varscan2
- ADGRL3 | c.3954G>A p.L1318= (on ENST00000506720 / NM_001322402.2; = p.L1207= on NM_015236.6) | Silent (SNP) | VAF 28/289 reads (10%) | catalogued as COSV101541156; called by muse, mutect2
- AHNAK | c.1206C>T p.P402= | Silent (SNP) | VAF 38/368 reads (10%) | catalogued as COSV57205329; called by muse, mutect2, varscan2
- ANKRD30A | c.3357C>T p.A1119= (on ENST00000611781; = p.A1063= on NM_052997.2) | Silent (SNP) | VAF 45/252 reads (18%) | catalogued as COSV64609532; called by muse, mutect2, varscan2
- ARC | c.195C>T p.H65= | Silent (SNP) | VAF 56/465 reads (12%) | catalogued as rs371846206; called by muse, mutect2, varscan2
- ARHGEF17 | c.2118C>T p.L706= | Silent (SNP) | VAF 92/505 reads (18%) | called by muse, mutect2, varscan2
- ASIC1 | c.921C>T p.I307= | Silent (SNP) | VAF 43/432 reads (10%) | called by muse, mutect2, varscan2
- ASPHD1 | c.738C>T p.A246= | Silent (SNP) | VAF 84/480 reads (18%) | called by muse, mutect2, varscan2
- ATG4A | c.933C>T p.I311= | Silent (SNP) | VAF 69/236 reads (29%) | called by muse, mutect2, varscan2
- ATP6V0D2 | c.648C>T p.A216= | Silent (SNP) | VAF 37/228 reads (16%) | catalogued as rs771991115, COSV53413025, COSV53418821; called by muse, mutect2, varscan2
- ATP6V1C2 | c.348G>A p.P116= | Silent (SNP) | VAF 31/373 reads (8%) | catalogued as rs746366093, COSV55359628; called by muse, mutect2
- ATPSCKMT | c.480C>T p.F160= | Silent (SNP) | VAF 37/360 reads (10%) | catalogued as rs758685178; called by muse, mutect2, varscan2
- ATRNL1 | c.3723C>T p.F1241= | Silent (SNP) | VAF 58/276 reads (21%) | catalogued as COSV58075062; called by muse, mutect2, varscan2
- BAD | c.129C>T p.G43= | Silent (SNP) | VAF 47/468 reads (10%) | called by muse, mutect2, varscan2
- BCL9L | c.45G>A p.R15= | Silent (SNP) | VAF 42/436 reads (10%) | called by muse, mutect2
- BMS1 | c.54T>C p.A18= | Silent (SNP) | VAF 58/496 reads (12%) | called by muse, mutect2
- BORA | c.984T>C p.P328= (on ENST00000613797; = p.P253= on NM_024808.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/282 reads (15%) | called by muse, mutect2, varscan2
- BRPF1 | c.2362C>T p.L788= | Silent (SNP) | VAF 111/476 reads (23%) | called by muse, mutect2, varscan2
- C10orf90 | c.1527C>T p.F509= | Silent (SNP) | VAF 46/310 reads (15%) | catalogued as COSV52954380; called by muse, mutect2, varscan2
- C16orf71 | c.141G>A p.G47= | Silent (SNP) | VAF 44/300 reads (15%) | called by muse, mutect2, varscan2
- C2CD2 | c.1305C>T p.S435= | Silent (SNP) | VAF 50/355 reads (14%) | catalogued as rs759140160, COSV61599535; called by muse, mutect2
- CACNA2D2 | c.2844C>T p.P948= (on ENST00000479441 / NM_001174051.3; = p.P941= on NM_006030.4) | Silent (SNP) | VAF 122/528 reads (23%) | called by muse, mutect2, varscan2
- CACNA2D3 | c.1875G>A p.G625= | Silent (SNP) | VAF 80/401 reads (20%) | catalogued as rs775916594, COSV55545618; called by muse, mutect2, varscan2
- CBX7 | c.546C>T p.V182= | Silent (SNP) | VAF 161/672 reads (24%) | catalogued as rs1244738609, COSV53359887; called by muse, mutect2, varscan2
- CCDC40 | c.3298C>T p.L1100= | Silent (SNP) | VAF 86/367 reads (23%) | catalogued as rs771675638; called by muse, mutect2, varscan2
- CCR2 | c.633G>A p.L211= | Silent (SNP) | VAF 72/503 reads (14%) | catalogued as rs769612183; called by muse, mutect2, varscan2
- CHD8 | c.1515G>A p.K505= (on ENST00000646647 / NM_001170629.2; = p.K226= on NM_020920.4) | Silent (SNP) | VAF 56/529 reads (11%) | catalogued as rs1317968114, COSV101303139; called by muse, mutect2, varscan2
- CHIA | c.379C>T p.L127= (on ENST00000343320; = p.L19= on NM_021797.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 61/402 reads (15%) | catalogued as rs369223512; called by muse, mutect2, varscan2
- CHRM4 | c.648C>T p.I216= | Silent (SNP) | VAF 105/459 reads (23%) | catalogued as rs1313912163; called by muse, mutect2, varscan2
- CHST4 | c.741G>A p.Q247= | Silent (SNP) | VAF 72/410 reads (18%) | called by muse, mutect2, varscan2
- CLPS | c.63C>T p.P21= | Silent (SNP) | VAF 80/552 reads (14%) | catalogued as rs1054340429; called by muse, mutect2, varscan2
- CNN3 | c.228C>T p.S76= | Silent (SNP) | VAF 54/326 reads (17%) | called by muse, mutect2, varscan2
- COL9A3 | c.1152G>A p.R384= | Silent (SNP) | VAF 94/550 reads (17%) | catalogued as rs769616163; called by muse, mutect2, varscan2
- CPLANE1 | c.42C>T p.F14= (on ENST00000425232; = p.F86= on NM_023073.3) | Silent (SNP) | VAF 39/255 reads (15%) | catalogued as COSV57060852; called by muse, mutect2, varscan2
- CRHBP | c.420C>T p.F140= | Silent (SNP) | VAF 55/468 reads (12%) | called by muse, mutect2, varscan2
- CTRC | c.585G>A p.R195= | Silent (SNP) | VAF 78/484 reads (16%) | catalogued as rs1408581495; called by muse, mutect2, varscan2
- CTXN2 | c.222G>A p.G74= | Silent (SNP) | VAF 31/250 reads (12%) | called by muse, mutect2, varscan2
- CYP4F22 | c.210C>T p.G70= | Silent (SNP) | VAF 46/335 reads (14%) | catalogued as rs1044324882; called by muse, mutect2, varscan2
- DDAH2 | c.309C>T p.V103= | Silent (SNP) | VAF 98/517 reads (19%) | catalogued as COSV65384407; called by muse, mutect2, varscan2
- DDX10 | c.684G>A p.L228= | Silent (SNP) | VAF 42/227 reads (19%) | called by muse, mutect2, varscan2
- DMD | c.4134C>T p.S1378= | Silent (SNP) | VAF 90/249 reads (36%) | called by muse, mutect2, varscan2
- DNAH1 | c.5421C>T p.D1807= | Silent (SNP) | VAF 76/480 reads (16%) | called by muse, mutect2, varscan2
- DNHD1 | c.9201C>T p.P3067= | Silent (SNP) | VAF 38/358 reads (11%) | catalogued as rs538098763, COSV54432180; called by muse, mutect2, varscan2
- DOK2 | c.498G>A p.L166= | Silent (SNP) | VAF 90/443 reads (20%) | catalogued as rs953387403; called by muse, mutect2, varscan2
- DOP1B | c.3663C>T p.V1221= | Silent (SNP) | VAF 80/482 reads (17%) | catalogued as rs375671793; called by muse, mutect2, varscan2
- DROSHA | c.306C>T p.F102= | Silent (SNP) | VAF 66/465 reads (14%) | called by muse, mutect2, varscan2
- EDIL3 | c.285C>T p.Y95= | Silent (SNP) | VAF 50/356 reads (14%) | called by muse, mutect2, varscan2
- EEF1AKNMT | c.525C>T p.S175= (on ENST00000361735 / NM_015935.5; = p.S89= on NM_014955.3) | Silent (SNP) | VAF 84/401 reads (21%) | called by muse, mutect2, varscan2
- EGR2 | c.732A>C p.P244= | Silent (SNP) | VAF 54/484 reads (11%) | called by muse, mutect2, varscan2
- EHD2 | c.534C>T p.F178= | Silent (SNP) | VAF 65/370 reads (18%) | catalogued as rs1381489142, COSV54406762; called by muse, mutect2, varscan2
- EML3 | c.528C>T p.S176= | Silent (SNP) | VAF 41/445 reads (9%) | catalogued as rs778486490; called by muse, mutect2
- EVPL | c.5475C>T p.F1825= | Silent (SNP) | VAF 102/496 reads (21%) | called by muse, mutect2
- EVX1 | c.873C>T p.S291= | Silent (SNP) | VAF 189/674 reads (28%) | catalogued as rs770776117; called by muse, mutect2, varscan2
- F2RL1 | c.1143G>A p.R381= | Silent (SNP) | VAF 48/363 reads (13%) | catalogued as COSV56996016; called by muse, mutect2, varscan2
- FAM117B | c.66G>T p.V22= | Silent (SNP) | VAF 121/612 reads (20%) | called by muse, mutect2, varscan2
- FER1L6 | c.3084C>T p.S1028= | Silent (SNP) | VAF 32/346 reads (9%) | catalogued as rs142391942, COSV67552266; called by muse, mutect2, varscan2
- FGF23 | c.234G>A p.E78= | Silent (SNP) | VAF 62/350 reads (18%) | called by muse, mutect2, varscan2
- FGGY | c.495G>A p.A165= | Silent (SNP) | VAF 47/289 reads (16%) | catalogued as rs1231817929, COSV100366330; called by muse, mutect2, varscan2
- FLT1 | c.3189G>A p.L1063= | Silent (SNP) | VAF 38/215 reads (18%) | called by muse, mutect2, varscan2
- FN1 | c.6315C>T p.L2105= (on ENST00000359671 / NM_001365524.2; = p.L2015= on NM_212476.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 106/493 reads (22%) | catalogued as COSV60561614; called by muse, mutect2, varscan2
- FNDC1 | c.1410G>A p.G470= | Silent (SNP) | VAF 63/283 reads (22%) | called by muse, mutect2, varscan2
- FOXP2 | c.993G>A p.S331= | Silent (SNP) | VAF 37/312 reads (12%) | catalogued as rs200003519, COSV100646128, COSV63488109; called by muse, mutect2, varscan2
- FPR2 | c.483C>T p.F161= | Silent (SNP) | VAF 75/359 reads (21%) | catalogued as rs1032794466, COSV60672924; called by muse, mutect2, varscan2
- FSHR | c.1350C>T p.V450= | Silent (SNP) | VAF 45/533 reads (8%) | called by muse, mutect2
- GEMIN2 | c.12G>A p.A4= | Silent (SNP) | VAF 44/293 reads (15%) | catalogued as rs969625033, COSV51627893; called by muse, varscan2
- GLP1R | c.414G>A p.E138= | Silent (SNP) | VAF 45/317 reads (14%) | catalogued as rs1440840142; called by muse, mutect2, varscan2
- GOLGA6L10 | c.105G>A p.R35= | Silent (SNP) | VAF 75/1067 reads (7%) | called by muse, mutect2
- GPRC5A | c.177C>T p.S59= | Silent (SNP) | VAF 76/456 reads (17%) | called by muse, mutect2, varscan2
- GRID1 | c.2364C>T p.I788= | Silent (SNP) | VAF 46/295 reads (16%) | catalogued as rs761831600; called by muse, mutect2, varscan2
- HACL1 | c.1230G>A p.Q410= | Silent (SNP) | VAF 54/356 reads (15%) | catalogued as COSV100337102; called by muse, mutect2, varscan2
- HDAC11 | c.735C>T p.S245= | Silent (SNP) | VAF 87/509 reads (17%) | catalogued as rs768915108, COSV55474694; called by muse, mutect2, varscan2
- HDLBP | c.204C>T p.I68= | Silent (SNP) | VAF 37/416 reads (9%) | called by muse, mutect2
- HIPK4 | c.327C>T p.P109= | Silent (SNP) | VAF 83/386 reads (22%) | catalogued as rs777921576, COSV52522739; called by muse, mutect2, varscan2
- HLTF | c.789C>T p.F263= | Silent (SNP) | VAF 67/439 reads (15%) | catalogued as rs143646223; called by muse, mutect2, varscan2
- HMCN1 | c.1818C>A p.L606= | Silent (SNP) | VAF 53/304 reads (17%) | called by muse, mutect2, varscan2
- HPX | c.717G>A p.R239= | Silent (SNP) | VAF 22/338 reads (7%) | called by muse, mutect2
- HUS1B | c.597C>T p.S199= | Silent (SNP) | VAF 75/385 reads (19%) | catalogued as rs1244806358; called by muse, mutect2, varscan2
- IFT140 | c.1551C>T p.F517= | Silent (SNP) | VAF 55/320 reads (17%) | catalogued as rs541830789, COSV101276300; called by muse, mutect2, varscan2
- IGSF21 | c.834C>T p.V278= | Silent (SNP) | VAF 81/555 reads (15%) | called by muse, mutect2, varscan2
- IL1R1 | c.1380C>T p.G460= | Silent (SNP) | VAF 45/355 reads (13%) | called by muse, mutect2, varscan2
- IQCN | c.3177G>A p.V1059= | Silent (SNP) | VAF 92/592 reads (16%) | catalogued as rs779698719; called by muse, mutect2, varscan2
- IRAK2 | c.912G>A p.S304= | Silent (SNP) | VAF 87/393 reads (22%) | catalogued as rs148137944; called by muse, mutect2, varscan2
- ITGA6 | c.2274C>T p.F758= (on ENST00000442250; = p.F719= on NM_000210.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/316 reads (10%) | called by muse, mutect2, varscan2
- ITPRIP | c.633C>T p.F211= | Silent (SNP) | VAF 67/483 reads (14%) | catalogued as rs905114549, COSV53390514; called by muse, mutect2, varscan2
- KANSL1 | c.1830C>T p.I610= | Silent (SNP) | VAF 80/390 reads (21%) | catalogued as rs150800846; called by muse, mutect2, varscan2
- KCND1 | c.1845C>T p.S615= | Silent (SNP) | VAF 125/321 reads (39%) | catalogued as COSV54414293; called by muse, mutect2, varscan2
- KCNQ4 | c.679C>T p.L227= | Silent (SNP) | VAF 77/349 reads (22%) | catalogued as COSV100714472; called by muse, mutect2, varscan2
- KCNS3 | c.195G>A p.K65= | Silent (SNP) | VAF 92/476 reads (19%) | called by muse, mutect2, varscan2
- KCNV1 | c.1002C>T p.S334= | Silent (SNP) | VAF 32/181 reads (18%) | called by muse, mutect2, varscan2
- KCTD14 | c.69C>T p.S23= | Silent (SNP) | VAF 82/441 reads (19%) | called by muse, mutect2, varscan2
- KDF1 | c.699C>T p.S233= | Silent (SNP) | VAF 64/429 reads (15%) | called by muse, mutect2, varscan2
- KIAA1109 | c.5352T>C p.G1784= | Silent (SNP) | VAF 26/328 reads (8%) | catalogued as rs200065287; called by muse, mutect2
- KIF14 | c.4125C>T p.I1375= | Silent (SNP) | VAF 71/406 reads (17%) | catalogued as COSV100950547, COSV66262599; called by muse, mutect2, varscan2
- KRT2 | c.909G>A p.V303= | Silent (SNP) | VAF 45/258 reads (17%) | called by muse, mutect2, varscan2
- KRT6C | c.624G>A p.Q208= | Silent (SNP) | VAF 98/330 reads (30%) | called by muse, varscan2
- LAMA5 | c.3423C>T p.S1141= | Silent (SNP) | VAF 67/445 reads (15%) | catalogued as COSV53372452; called by muse, mutect2, varscan2
- LIN28A | c.264G>A p.K88= | Silent (SNP) | VAF 68/424 reads (16%) | called by muse, mutect2, varscan2
- LINGO1 | c.780C>T p.L260= | Silent (SNP) | VAF 61/414 reads (15%) | catalogued as rs1319319245; called by muse, mutect2, varscan2
- LTBP2 | c.2052C>T p.T684= | Silent (SNP) | VAF 82/478 reads (17%) | catalogued as rs756731827; called by muse, mutect2, varscan2
- LY6G6F | c.834C>T p.I278= | Silent (SNP) | VAF 115/593 reads (19%) | called by muse, mutect2, varscan2
- MAGI3 | c.3117G>A p.K1039= | Silent (SNP) | VAF 81/465 reads (17%) | called by muse, mutect2, varscan2
- MFSD2A | c.1029G>A p.Q343= (on ENST00000372809 / NM_001136493.3; = p.Q330= on NM_032793.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 42/247 reads (17%) | called by muse, mutect2, varscan2
- MMEL1 | c.1878C>T p.F626= | Silent (SNP) | VAF 60/295 reads (20%) | catalogued as rs773695354, COSV56522951, COSV56525972; called by muse, mutect2, varscan2
- MN1 | c.3573G>A p.G1191= | Silent (SNP) | VAF 108/573 reads (19%) | called by muse, mutect2, varscan2
- MRGPRX1 | c.591C>T p.V197= | Silent (SNP) | VAF 39/201 reads (19%) | catalogued as rs1207784648, COSV57107155; called by muse, mutect2, varscan2
- MROH2A | c.1959C>T p.S653= | Silent (SNP) | VAF 28/272 reads (10%) | called by muse, mutect2
- MUC12 | c.10947C>T p.F3649= (on ENST00000379442; = p.F3506= on NM_001164462.1) | Silent (SNP) | VAF 104/1748 reads (6%) | called by muse, mutect2
- MUC16 | c.31756C>T p.L10586= | Silent (SNP) | VAF 55/388 reads (14%) | catalogued as rs367944460; called by muse, mutect2, varscan2
- MUC16 | c.3954C>T p.T1318= | Silent (SNP) | VAF 76/513 reads (15%) | called by muse, mutect2, varscan2
- NBEAL1 | c.7890C>T p.I2630= | Silent (SNP) | VAF 35/465 reads (8%) | called by muse, mutect2
- NBPF9 | c.1965C>T p.P655= | Silent (SNP) | VAF 21/564 reads (4%) | catalogued as rs1436138530; called by muse, mutect2
- NDST3 | c.1716C>T p.L572= | Silent (SNP) | VAF 22/238 reads (9%) | called by muse, mutect2
- NDUFS6 | c.21C>T p.F7= | Silent (SNP) | VAF 38/422 reads (9%) | catalogued as rs765658739; called by muse, mutect2
- NRDE2 | c.2853C>T p.S951= | Silent (SNP) | VAF 98/396 reads (25%) | catalogued as rs1342814466; called by muse, mutect2, varscan2
- NUGGC | c.1296C>G p.L432= | Silent (SNP) | VAF 44/309 reads (14%) | called by muse, mutect2, varscan2
- OIT3 | c.324C>T p.F108= | Silent (SNP) | VAF 70/579 reads (12%) | called by muse, mutect2, varscan2
- OR14I1 | c.186G>A p.K62= | Silent (SNP) | VAF 89/546 reads (16%) | catalogued as COSV61200840; called by muse, mutect2
- OR2A7 | c.51C>T p.P17= | Silent (SNP) | VAF 55/694 reads (8%) | catalogued as rs759972336; called by muse, mutect2
- OR2F2 | c.765G>A p.T255= | Silent (SNP) | VAF 116/442 reads (26%) | catalogued as rs866839513, COSV68832568; called by muse, mutect2, varscan2
- OR2G6 | c.795G>A p.R265= | Silent (SNP) | VAF 73/426 reads (17%) | catalogued as COSV58575923; called by muse, mutect2, varscan2
- OR4Q2 | c.762C>T p.F254= | Silent (SNP) | VAF 70/351 reads (20%) | catalogued as rs958357773; called by muse, mutect2, varscan2
- OR51S1 | c.324G>A p.Q108= | Silent (SNP) | VAF 84/387 reads (22%) | catalogued as rs372829309; called by muse, mutect2, varscan2
- OR52J3 | c.630G>A p.L210= | Silent (SNP) | VAF 88/410 reads (21%) | called by muse, mutect2, varscan2
- OR5A2 | c.15G>A p.R5= | Silent (SNP) | VAF 25/225 reads (11%) | called by muse, mutect2, varscan2
- PAX8 | c.811C>T p.L271= | Silent (SNP) | VAF 84/476 reads (18%) | called by muse, mutect2, varscan2
- PCDHB2 | c.807G>A p.R269= | Silent (SNP) | VAF 41/394 reads (10%) | catalogued as COSV99522925, COSV99523305; called by muse, mutect2, varscan2
- PDZD2 | c.3615G>A p.L1205= | Silent (SNP) | VAF 66/395 reads (17%) | called by muse, mutect2, varscan2
- PFKFB4 | c.801G>A p.R267= | Silent (SNP) | VAF 111/544 reads (20%) | catalogued as COSV51682657; called by muse, mutect2, varscan2
- PIK3CG | c.126C>T p.F42= | Silent (SNP) | VAF 160/550 reads (29%) | catalogued as COSV63245522; called by muse, mutect2, varscan2
- PKHD1 | c.5532C>T p.S1844= | Silent (SNP) | VAF 91/464 reads (20%) | called by muse, mutect2, varscan2
- PLD1 | c.1164C>T p.F388= | Silent (SNP) | VAF 61/369 reads (17%) | called by muse, mutect2, varscan2
- PLXNA1 | c.1458C>T p.I486= | Silent (SNP) | VAF 98/528 reads (19%) | called by muse, mutect2, varscan2
- POLR2A | c.402G>A p.K134= | Silent (SNP) | VAF 24/332 reads (7%) | catalogued as rs758743434; called by muse, mutect2
- PPARGC1B | c.1633C>T p.L545= | Silent (SNP) | VAF 69/437 reads (16%) | catalogued as rs137977806; called by muse, mutect2, varscan2
- PPP1R42 | c.927C>T p.S309= | Silent (SNP) | VAF 18/216 reads (8%) | called by muse, mutect2
- PRAMEF20 | c.1062G>A p.L354= | Silent (SNP) | VAF 64/431 reads (15%) | called by muse, mutect2, varscan2
- PROSER2 | c.651C>T p.F217= | Silent (SNP) | VAF 88/656 reads (13%) | called by muse, mutect2, varscan2
- PROSER3 | c.1131G>A p.E377= | Silent (SNP) | VAF 95/524 reads (18%) | called by muse, mutect2, varscan2
- PRR30 | c.738C>T p.V246= | Silent (SNP) | VAF 47/489 reads (10%) | catalogued as rs775724854; called by muse, mutect2
- PTGFR | c.771C>T p.V257= | Silent (SNP) | VAF 68/352 reads (19%) | called by muse, mutect2, varscan2
- PTPRU | c.3306G>A p.L1102= | Silent (SNP) | VAF 89/475 reads (19%) | called by muse, mutect2, varscan2
- PTPRZ1 | c.4938C>T p.A1646= | Silent (SNP) | VAF 38/492 reads (8%) | called by muse, mutect2
- RANBP17 | c.666C>T p.V222= | Silent (SNP) | VAF 65/354 reads (18%) | called by muse, mutect2, varscan2
- RET | c.3153C>T p.A1051= | Silent (SNP) | VAF 64/444 reads (14%) | called by muse, mutect2, varscan2
- RNF212B | c.639C>T p.T213= | Silent (SNP) | VAF 53/334 reads (16%) | called by muse, mutect2, varscan2
- RP1 | c.1986G>A p.K662= | Silent (SNP) | VAF 33/362 reads (9%) | called by muse, mutect2
- RPS6KL1 | c.180C>T p.A60= | Silent (SNP) | VAF 86/458 reads (19%) | called by muse, mutect2, varscan2
- SAMD9 | c.1566G>A p.R522= | Silent (SNP) | VAF 38/445 reads (9%) | catalogued as COSV66076890; called by muse, mutect2
- SEMA6B | c.285C>T p.S95= | Silent (SNP) | VAF 93/513 reads (18%) | called by muse, mutect2, varscan2
- SH3BP2 | c.30C>T p.A10= | Silent (SNP) | VAF 42/526 reads (8%) | called by muse, mutect2
- SLC16A8 | c.1413G>A p.E471= | Silent (SNP) | VAF 104/510 reads (20%) | called by muse, mutect2, varscan2
- SLC29A3 | c.1095C>T p.L365= | Silent (SNP) | VAF 125/608 reads (21%) | catalogued as COSV64384877; called by muse, mutect2, varscan2
- SLC39A7 | c.144G>A p.R48= | Silent (SNP) | VAF 136/838 reads (16%) | called by muse, mutect2, varscan2
- SLC6A6 | c.786C>T p.V262= | Silent (SNP) | VAF 59/462 reads (13%) | called by muse, mutect2, varscan2
- SLC7A11 | c.1143C>T p.F381= | Silent (SNP) | VAF 38/356 reads (11%) | called by muse, mutect2, varscan2
- SMAD6 | c.591C>T p.S197= | Silent (SNP) | VAF 58/424 reads (14%) | called by muse, mutect2, varscan2
- SPATA18 | c.168G>A p.G56= | Silent (SNP) | VAF 34/395 reads (9%) | called by muse, mutect2
- SPRY2 | c.423C>T p.S141= | Silent (SNP) | VAF 78/460 reads (17%) | catalogued as rs749285299; called by muse, mutect2, varscan2
- STAB2 | c.1392C>T p.I464= | Silent (SNP) | VAF 36/237 reads (15%) | called by muse, mutect2, varscan2
- STK25 | c.873G>A p.K291= | Silent (SNP) | VAF 46/429 reads (11%) | called by muse, mutect2, varscan2
- TANGO2 | c.316C>T p.L106= | Silent (SNP) | VAF 57/277 reads (21%) | called by muse, mutect2, varscan2
- TBCB | c.522T>C p.P174= | Silent (SNP) | VAF 91/507 reads (18%) | called by muse, mutect2, varscan2
- TBR1 | c.330C>T p.S110= | Silent (SNP) | VAF 56/503 reads (11%) | called by muse, mutect2
- THNSL2 | c.447C>T p.A149= | Silent (SNP) | VAF 32/350 reads (9%) | called by muse, mutect2, varscan2
- TMEM131 | c.4080C>T p.H1360= | Silent (SNP) | VAF 38/468 reads (8%) | catalogued as COSV51773839; called by muse, mutect2
- TMEM132C | c.480C>T p.D160= | Silent (SNP) | VAF 64/666 reads (10%) | catalogued as rs915630290; called by muse, mutect2
- TMEM238L | c.84C>T p.V28= | Silent (SNP) | VAF 57/320 reads (18%) | catalogued as rs776796060; called by muse, mutect2, varscan2
- TMEM63C | c.1629C>T p.A543= | Silent (SNP) | VAF 64/330 reads (19%) | called by muse, mutect2, varscan2
- TPGS1 | c.816G>A p.E272= | Silent (SNP) | VAF 51/451 reads (11%) | called by muse, mutect2
- TRAV26-1 | c.6G>A p.R2= | Silent (SNP) | VAF 59/254 reads (23%) | called by muse, mutect2, varscan2
- TRIM24 | c.2391C>T p.S797= (on ENST00000343526 / NM_015905.3; = p.S763= on NM_003852.4) | Silent (SNP) | VAF 130/464 reads (28%) | called by muse, mutect2, varscan2
- TRIM49C | c.255C>T p.F85= | Silent (SNP) | VAF 58/268 reads (22%) | called by muse, mutect2, varscan2
- TRIM71 | c.1929C>T p.F643= | Silent (SNP) | VAF 85/508 reads (17%) | catalogued as rs757175523, COSV67470563; called by muse, mutect2, varscan2
- TRPA1 | c.2637C>T p.F879= | Silent (SNP) | VAF 18/239 reads (8%) | called by muse, mutect2
- TRPA1 | c.1773G>A p.K591= | Silent (SNP) | VAF 49/246 reads (20%) | called by muse, mutect2, varscan2
- TSGA13 | c.291G>A p.L97= | Silent (SNP) | VAF 152/521 reads (29%) | called by muse, mutect2, varscan2
- TSHB | c.54G>A p.A18= | Silent (SNP) | VAF 75/502 reads (15%) | catalogued as rs188599368; called by muse, mutect2
- TTC29 | c.396G>A p.R132= | Silent (SNP) | VAF 23/244 reads (9%) | called by muse, mutect2
- TTC6 | c.1413A>G p.E471= (on ENST00000267368; = p.E1837= on NM_001310135.3) | Silent (SNP) | VAF 37/243 reads (15%) | called by muse, mutect2, varscan2
- TTN | c.75423C>T p.S25141= (on ENST00000591111; = p.S17717= on NM_003319.4) | Silent (SNP) | VAF 72/346 reads (21%) | catalogued as COSV60152331; called by muse, mutect2, varscan2
- UGT1A6 | c.531C>T p.S177= | Silent (SNP) | VAF 98/508 reads (19%) | catalogued as COSV59394517; called by muse, mutect2, varscan2
- VASP | c.354C>T p.P118= | Silent (SNP) | VAF 64/442 reads (14%) | called by muse, mutect2, varscan2
- VPS8 | c.3843C>T p.G1281= (on ENST00000625842 / NM_001349294.1; = p.G1279= on NM_015303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 59/304 reads (19%) | called by muse, mutect2, varscan2
- WIZ | c.5664T>G p.A1888= (on ENST00000673675 / NM_001371589.1; = p.A793= on NM_021241.3) | Silent (SNP) | VAF 60/381 reads (16%) | called by muse, mutect2, varscan2
- XIRP2 | c.1167G>A p.L389= (on ENST00000628543; = p.L564= on NM_152381.6) | Silent (SNP) | VAF 29/362 reads (8%) | called by muse, mutect2
- XKR3 | c.252C>T p.I84= | Silent (SNP) | VAF 64/330 reads (19%) | catalogued as COSV58886152; called by muse, mutect2, varscan2
- XYLT1 | c.2364C>T p.V788= | Silent (SNP) | VAF 79/540 reads (15%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73847623 G>C | 5'Flank (SNP) | VAF 14/168 reads (8%) | called by muse, mutect2
- ANAPC15 | chr11:72107411 G>A | 3'Flank (SNP) | VAF 41/377 reads (11%) | called by muse, mutect2, varscan2
- ARHGAP33 | c.1943-97C>A | Intron (SNP) | VAF 84/422 reads (20%) | catalogued as rs770263144, COSV50135466; called by muse, mutect2, varscan2
- BAD | c.*143C>T | 3'UTR (SNP) | VAF 56/286 reads (20%) | catalogued as COSV99657319; called by muse, mutect2, varscan2
- C18orf25 | c.716-11171G>C | Intron (SNP) | VAF 60/401 reads (15%) | called by muse, mutect2, varscan2
- C2orf16 | chr2:27571709 G>A | 5'Flank (SNP) | VAF 83/347 reads (24%) | called by muse, mutect2, varscan2
- DCHS2 | n.8623C>T | RNA (SNP) | VAF 47/406 reads (12%) | catalogued as rs751062395; called by muse, mutect2, varscan2
- DCHS2 | n.686C>T | RNA (SNP) | VAF 16/210 reads (8%) | called by muse, mutect2
- DNAH10 | c.13307-226C>T | Intron (SNP) | VAF 47/436 reads (11%) | catalogued as rs1159942024; called by muse, varscan2
- DNALI1 | c.-1C>T | 5'UTR (SNP) | VAF 65/318 reads (20%) | catalogued as rs1029855525; called by muse, mutect2, varscan2
- FAM13C | c.508-58C>T | Intron (SNP) | VAF 52/419 reads (12%) | called by muse, mutect2, varscan2
- GALNT16 | c.1539+57G>A | Intron (SNP) | VAF 56/492 reads (11%) | called by muse, mutect2, varscan2
- GRM4 | c.520-9927G>A | Intron (SNP) | VAF 48/311 reads (15%) | called by muse, mutect2, varscan2
- IL15 | c.110+583A>T | Intron (SNP) | VAF 28/264 reads (11%) | called by muse, mutect2, varscan2
- KIF16B | c.3498+3419C>T | Intron (SNP) | VAF 31/274 reads (11%) | catalogued as rs1164938698; called by muse, mutect2, varscan2
- LSM11 | c.*387C>T | 3'UTR (SNP) | VAF 50/439 reads (11%) | called by muse, mutect2, varscan2
- LSP1 | c.54-13229G>A | Intron (SNP) | VAF 102/571 reads (18%) | called by muse, mutect2, varscan2
- MACF1 | c.15832-11759G>A | Intron (SNP) | VAF 62/412 reads (15%) | called by muse, mutect2, varscan2
- PDE4A | c.320+9891C>T | Intron (SNP) | VAF 107/529 reads (20%) | called by muse, mutect2, varscan2
- RBM44 | c.-98-2597G>A | Intron (SNP) | VAF 54/315 reads (17%) | catalogued as COSV57627259; called by muse, mutect2, varscan2
- RPP30 | chr10:90903250 G>A | 3'Flank (SNP) | VAF 40/301 reads (13%) | catalogued as COSV65471870; called by muse, mutect2, varscan2
- SHISA8 | chr22:41910433 G>A | 3'Flank (SNP) | VAF 71/435 reads (16%) | catalogued as rs1485165483; called by muse, mutect2, varscan2
- SIRPB1 | c.76+15732C>T | Intron (SNP) | VAF 22/150 reads (15%) | called by muse, mutect2, varscan2
- SNAP25 | c.164-262G>A | Intron (SNP) | VAF 33/281 reads (12%) | catalogued as rs1431916684, COSV54770791; called by muse, mutect2, varscan2
- TCIM | c.*155G>A | 3'UTR (SNP) | VAF 42/373 reads (11%) | catalogued as rs1330570342; called by muse, mutect2, varscan2
- TPM1 | c.115-206C>T | Intron (SNP) | VAF 47/520 reads (9%) | called by muse, mutect2
- TULP3 | c.*1263C>T | 3'UTR (SNP) | VAF 47/312 reads (15%) | called by muse, mutect2, varscan2
- WDR45 | c.*192G>A | 3'UTR (SNP) | VAF 75/355 reads (21%) | called by muse, mutect2, varscan2
